Somatic mutation profile of tumor specimen TCGA-HU-8238-01A (aliquot TCGA-HU-8238-01A-11D-2340-08) from TCGA case TCGA-HU-8238, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; Tumor grade: G2; Age at diagnosis: 56.7 years (20,708 days).
Specimen TCGA-HU-8238-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63f50ca1-c4f0-4527-b944-1d86a9cc9104.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-8238-10A (Blood Derived Normal), aliquot TCGA-HU-8238-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d590044-bea4-4acc-adb4-4611f4d15964

The open-access MAF lists 184 somatic variants for this specimen: 141 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 37, Nonsense Mutation 10, Frame Shift Del 5, RNA 3, Intron 2, In Frame Del 2, Splice Site 2, Frame Shift Ins 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD11 | c.3008A>C p.K1003T (on ENST00000280758 / NM_001018072.2; = p.K540T on NM_001017523.2) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as COSV55025836, COSV55028973, COSV55038748; called by muse, mutect2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 32/114 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+2T>C p.X224_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | hotspot (GDC flag); catalogued as CS034998, CS0910926, COSV52677962, COSV52797769, COSV53179168; called by muse, mutect2
- ADAMTSL1 | c.1538A>T p.E513V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99444712; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4222A>C p.T1408P | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99721065; called by muse, mutect2, varscan2
- ADGRL2 | c.4120A>C p.S1374R (on ENST00000370717 / NM_001366005.1; = p.S1318R on NM_012302.4) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54667456; called by muse, mutect2, varscan2
- ALPP | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101235187; called by muse, mutect2, varscan2
- ANO3 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs745681189, COSV99885528; called by muse, mutect2, varscan2
- ARHGAP22 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99985952; called by muse, mutect2, varscan2
- ARHGAP31 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs752428737, COSV99957393; called by muse, mutect2, varscan2
- ARPP21 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs140987024; called by muse, mutect2, varscan2
- ATP2B1 | c.1063C>G p.P355A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV99666130; called by muse, mutect2, varscan2
- BANK1 | c.1939G>T p.D647Y | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59846498; called by muse, mutect2, varscan2
- BICC1 | c.2078A>C p.K693T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99570879; called by muse, mutect2, varscan2
- C12orf56 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV61490539; called by muse, mutect2, varscan2
- C12orf66 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV100320664; called by muse, mutect2, varscan2
- CABCOCO1 | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100358070; called by muse, mutect2, varscan2
- CABP5 | c.433dup p.R145Pfs*5 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | catalogued as rs769959570; called by mutect2, pindel
- CACNA1D | c.28del p.M10Cfs*60 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | catalogued as COSV55457798; called by mutect2, varscan2
- CEP57 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100334817; called by muse, mutect2, varscan2
- CLEC1A | c.384A>C p.K128N | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100191733; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- COL6A3 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs745667305, COSV99798957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); catalogued as rs201557549, COSV100097637; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL8A1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.134); catalogued as rs757127478, COSV99658428; called by muse, mutect2, varscan2
- CPOX | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99939182; called by muse, mutect2, varscan2
- CPXM1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV66045924; called by muse, mutect2, varscan2
- CYP2R1 | c.409A>T p.R137* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100584997; called by muse, mutect2, varscan2
- CYP2R1 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV100584998; called by muse, mutect2, varscan2
- DDX10 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV59436169; called by muse, mutect2, varscan2
- DDX27 | c.2071A>C p.K691Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as COSV100872046, COSV100872618; called by muse, mutect2, varscan2
- DGKH | c.3059T>G p.L1020R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV99819539; called by muse, mutect2, varscan2
- DKKL1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99678790; called by muse, mutect2, varscan2
- DPP6 | c.1334A>C p.K445T (on ENST00000377770 / NM_001364500.2; = p.K383T on NM_001936.5) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.386); catalogued as COSV59602140, COSV59626682; called by muse, mutect2, varscan2
- DSE | c.2114G>T p.G705V | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.088); catalogued as COSV100528794; called by muse, mutect2, varscan2
- DST | c.12071G>A p.R4024Q (on ENST00000361203 / NM_001374722.1; = p.R1612Q on NM_015548.5) | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1213650979, COSV99756008; called by muse, mutect2, varscan2
- DST | c.11814G>A p.W3938* (on ENST00000361203 / NM_001374722.1; = p.W1526* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 35/111 reads (32%) | catalogued as COSV99759719; called by muse, mutect2, varscan2
- EEA1 | c.2410A>G p.K804E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100468472; called by muse, mutect2, varscan2
- EMC9 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV99246490; called by muse, mutect2, varscan2
- ERICH3 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as COSV100445665; called by muse, mutect2, varscan2
- ETV3L | c.251A>T p.K84I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101485611; called by mutect2, varscan2
- FAM181A | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752834933, COSV99967987; called by muse, mutect2, varscan2
- FBXL17 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV62849595; called by muse, mutect2, varscan2
- FERMT2 | c.610A>C p.T204P | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as COSV100449136; called by muse, mutect2, varscan2
- FLG2 | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 80/322 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs972043961, COSV66174752; called by muse, mutect2, varscan2
- FRMPD3 | c.3730C>T p.R1244* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99347025; called by muse, mutect2, varscan2
- FRS3 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV99443135; called by muse, mutect2, varscan2
- FSCB | c.1037T>G p.L346R | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV100469835, COSV61219798; called by muse, mutect2, varscan2
- GNB2 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99309976; called by muse, mutect2, varscan2
- GOLGA2 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV101425961; called by muse, mutect2, varscan2
- GPR158 | c.2972A>C p.N991T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100894260; called by muse, mutect2, varscan2
- GREM2 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as rs753407682, COSV100547923, COSV100547973; called by muse, mutect2, varscan2
- GRIN1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.187); catalogued as rs748041860, COSV100160691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HECA | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100866251; called by muse, mutect2, varscan2
- HNRNPK | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100699130; called by muse, mutect2, varscan2
- HOXD12 | c.573C>T p.D191= | Splice Region (SNP) | VAF 8/19 reads (42%) | catalogued as rs200423501, COSV101184240; called by muse, mutect2, varscan2
- IFT172 | c.2392C>A p.L798M | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as COSV99563261; called by muse, varscan2
- IL16 | c.3892T>G p.F1298V (on ENST00000302987 / NM_172217.5; = p.F597V on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV100250924; called by muse, mutect2, varscan2
- KCND2 | c.520del p.A174Pfs*65 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as COSV58595581; called by mutect2, pindel, varscan2
- KCND2 | c.1735A>G p.K579E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); catalogued as COSV100478421; called by muse, mutect2, varscan2
- KIF21A | c.445T>A p.L149I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100735635; called by muse, mutect2, varscan2
- KIF24 | c.1039T>G p.S347A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV100799330; called by muse, mutect2, varscan2
- KLF14 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60588390; called by muse, mutect2, varscan2
- LARP1B | c.2102T>A p.L701H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99218910; called by muse, mutect2, varscan2
- LMOD2 | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.998); catalogued as COSV101505466; called by muse, mutect2
- LRRC30 | c.221A>G p.Q74R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as COSV101274455; called by muse, mutect2, varscan2
- LTK | c.1859T>C p.L620P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as COSV99541170; called by muse, mutect2, varscan2
- MAP2K7 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV101209141; called by muse, mutect2, varscan2
- MAP4K2 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs762109609, COSV99581664; called by muse, mutect2, varscan2
- MIOS | c.663C>G p.F221L | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.088); catalogued as COSV100402875, COSV100402949, COSV60767197; called by muse, mutect2, varscan2
- MORC1 | c.2825A>G p.Q942R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV99227701; called by muse, mutect2, varscan2
- MRTFB | c.3204C>G p.N1068K (on ENST00000571589 / NM_001365412.2; = p.N1018K on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100371803; called by muse, mutect2, varscan2
- MS4A13 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV100981205; called by muse, mutect2, varscan2
- MVB12A | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.596); catalogued as COSV100396380, COSV100396605; called by muse, mutect2, varscan2
- MYO16 | c.298-1G>C p.X100_splice | Splice Site (SNP) | VAF 19/86 reads (22%) | catalogued as rs1180851593, COSV99194574; called by muse, mutect2, varscan2
- NALCN | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745318137, COSV99217547; called by muse, varscan2
- NEDD4 | c.2268A>T p.Q756H (on ENST00000508342 / NM_001284338.1; = p.Q337H on NM_006154.4) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV100164090; called by muse, mutect2, varscan2
- NLRP12 | c.2296C>G p.L766V | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV100145865; called by muse, mutect2, varscan2
- OBSCN | c.11728C>A p.Q3910K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.82); PolyPhen benign (0.118); catalogued as COSV99484023; called by muse, mutect2, varscan2
- OR1L6 | c.596T>A p.L199H (on ENST00000373684; = p.L163H on NM_001004453.2) | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100490991; called by muse, mutect2, varscan2
- OR52E8 | c.879T>G p.N293K | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101190978; called by muse, mutect2, varscan2
- ORC3 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100006268; called by muse, mutect2, varscan2
- PANK1 | c.1516C>T p.R506* (on ENST00000307534 / NM_148977.2; = p.R222* on NM_138316.4) | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as rs932552792, COSV100285801; called by muse, mutect2, varscan2
- PCDH18 | c.981A>C p.Q327H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61266332, COSV61268397; called by muse, mutect2, varscan2
- PCDH9 | c.2324A>C p.N775T | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100123358, COSV60551778; called by muse, mutect2, varscan2
- PDE10A | c.1522T>G p.L508V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV100605710; called by muse, mutect2, varscan2
- PDLIM2 | c.466C>A p.Q156K (on ENST00000397760; = p.Q406K on NM_021630.6) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV99747902; called by muse, mutect2, varscan2
- PI4KA | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs767131535, COSV99748461; called by muse, mutect2, varscan2
- PKDREJ | c.2774C>A p.S925* | Nonsense Mutation (SNP) | VAF 55/187 reads (29%) | catalogued as COSV53547000, COSV99479485; called by muse, mutect2, varscan2
- PLCE1 | c.1540A>C p.S514R | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.409); catalogued as COSV99597046; called by muse, mutect2, varscan2
- PLCL1 | c.1975T>C p.F659L | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.101); catalogued as COSV101407279; called by muse, varscan2
- PLK1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as COSV100267457; called by muse, mutect2, varscan2
- PLSCR4 | c.845T>C p.L282S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100724342; called by muse, mutect2, varscan2
- PPFIA2 | c.2191A>T p.S731C | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100335140; called by muse, mutect2, varscan2
- PPFIA4 | c.2918G>A p.R973H (on ENST00000447715; = p.R974H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1410964055, COSV55315741; called by muse, mutect2
- PRAMEF6 | c.1310A>C p.E437A | Missense Mutation (SNP) | VAF 59/456 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV100755907; called by muse, mutect2, varscan2
- PRKAG2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.088); catalogued as rs564358410, COSV55224669; called by muse, mutect2, varscan2
- PTGER4 | c.1201C>G p.L401V | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV100201749; called by muse, mutect2, varscan2
- PTPRO | c.114_116del p.N39del | In Frame Del (DEL) | VAF 36/106 reads (34%) | catalogued as rs552861208; called by pindel, varscan2
- PTPRT | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776642212, COSV61959822; called by muse, mutect2, varscan2
- RALGAPA1 | c.3305G>C p.R1102T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99354236, COSV99356007; called by muse, mutect2, varscan2
- RCL1 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs371417592, COSV101099455; called by muse, mutect2, varscan2
- RERG | c.271A>C p.S91R | Missense Mutation (SNP) | VAF 167/442 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99917370; called by muse, mutect2, varscan2
- RIMS2 | c.1342T>G p.L448V (on ENST00000666250 / NM_001348490.2; = p.L256V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV51669105, COSV51676746; called by muse, mutect2, varscan2
- RRBP1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV55708628; called by muse, mutect2, varscan2
- SACS | c.12656G>C p.S4219T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV101207715; called by muse, mutect2, varscan2
- SAMD9 | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs1249495254, COSV66076372; called by muse, mutect2, varscan2
- SEMA3E | c.2092G>T p.A698S | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100319564; called by muse, mutect2, varscan2
- SON | c.4612A>G p.N1538D | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99279711; called by muse, mutect2, varscan2
- SPAG11B | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs375334909; called by mutect2, varscan2
- SPIDR | c.2236C>G p.L746V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV99856013; called by muse, mutect2, varscan2
- SRRM4 | c.242A>C p.K81T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as COSV99939377; called by muse, mutect2, varscan2
- STARD3 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as rs149648909, COSV100302837; called by muse, mutect2, varscan2
- SYNM | c.1457G>C p.S486T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100153034; called by muse, mutect2, varscan2
- TAC4 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as rs776223037, COSV100402802; called by muse, mutect2, varscan2
- THSD7B | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV55704552; called by muse, mutect2, varscan2
- TIAM2 | c.4468C>T p.H1490Y (on ENST00000529824; = p.H1461Y on NM_012454.3) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as COSV51639213; called by muse, mutect2
- TRIM5 | c.1388A>C p.K463T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.817); catalogued as COSV59901147; called by muse, mutect2, varscan2
- TTC13 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100793022; called by muse, mutect2, varscan2
- TTC6 | c.494T>C p.V165A (on ENST00000267368; = p.V1531A on NM_001310135.3) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV99942255; called by muse, mutect2, varscan2
- UBE2NL | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs781838711; called by muse, mutect2
- USP29 | c.1469A>C p.K490T | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV54140041, COSV54145541; called by muse, mutect2, varscan2
- VWF | c.3869A>T p.E1290V | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99780088; called by muse, mutect2
- VWF | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs61748472, CM951302, COSV99779834, COSV99780090; ClinVar: not provided; called by muse, mutect2, varscan2
- WNT7A | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746475689, COSV53199311; called by muse, mutect2, varscan2
- WT1 | c.1432T>C p.F478L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100188871; called by muse, mutect2, varscan2
- XDH | c.3931G>A p.V1311M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as COSV65148297; called by muse, mutect2, varscan2
- ZBTB11 | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV100465820; called by muse, mutect2, varscan2
- ZC3H12A | c.617A>T p.K206M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201388317, COSV66104124; called by muse, mutect2, varscan2
- ZNF208 | c.948A>C p.K316N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.581); catalogued as COSV101237199, COSV68099423, COSV68111580; called by muse, mutect2, varscan2
- ZNF568 | c.794T>A p.L265H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100451439; called by muse, mutect2, varscan2
- ZNF577 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs45526832, COSV100031292; called by muse, mutect2, varscan2
- ACACA | c.6581G>C p.S2194T | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BOC | c.585_592del p.G196Qfs*29 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | called by mutect2, pindel*, varscan2
- CDH7 | c.201del p.Y67* | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel*, varscan2
- FAM47B | c.1790_1797del p.L597Rfs*9 | Frame Shift Del (DEL) | VAF 42/105 reads (40%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- OR1L4 | c.488T>A p.L163H | Missense Mutation (SNP) | VAF 37/384 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- RUNX2 | c.195_206del p.Q68_Q71del | In Frame Del (DEL) | VAF 5/16 reads (31%) | called by muse*, mutect2, varscan2*
- SLC12A3 | c.2454dup p.T819Hfs*20 (on ENST00000563236 / NM_001126108.2; = p.T828Hfs*20 on NM_000339.3) | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- ZNF605 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- AKR1E2 | c.810C>T p.T270= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV100033680; called by muse, mutect2, varscan2
- BEND3 | c.768C>T p.I256= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs782314128, COSV64681126; called by muse, mutect2, varscan2
- BPIFA2 | c.33C>T p.C11= | Silent (SNP) | VAF 40/176 reads (23%) | catalogued as rs771075584, COSV53610353; called by muse, mutect2, varscan2
- CALHM1 | c.138G>A p.P46= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs200373153, COSV61707817; called by muse, mutect2, varscan2
- CASZ1 | c.1368C>T p.A456= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs151200081, COSV100682227; called by muse, mutect2, varscan2
- COL22A1 | c.2388A>T p.R796= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100280672, COSV57342501; called by muse, mutect2, varscan2
- CPE | c.828C>G p.A276= | Silent (SNP) | VAF 54/184 reads (29%) | catalogued as COSV101291710; called by muse, mutect2, varscan2
- CTNNBL1 | c.876G>A p.Q292= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100799829; called by muse, mutect2, varscan2
- DENND4A | c.2541T>G p.T847= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV101475427; called by muse, mutect2, varscan2
- EML2 | c.1863G>A p.V621= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV55603567; called by muse, mutect2, varscan2
- ERAP1 | c.1245C>T p.S415= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99701276; called by muse, mutect2, varscan2
- FASTKD3 | c.1362A>T p.S454= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as COSV99242088; called by muse, mutect2, varscan2
- GRK6 | c.1539C>T p.N513= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs375413182; called by muse, mutect2, varscan2
- HAS2 | c.279A>G p.Q93= | Silent (SNP) | VAF 58/274 reads (21%) | catalogued as rs770612273, COSV100391883, COSV100392175; called by muse, mutect2, varscan2
- HSF1 | c.639G>A p.L213= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV100184205; called by muse, mutect2, varscan2
- IGKV1-9 | c.99G>T p.L33= | Silent (SNP) | VAF 48/193 reads (25%) | called by muse, mutect2, varscan2
- KIAA1328 | c.1107A>G p.Q369= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV99695335; called by muse, mutect2
- KRT86 | c.717G>C p.L239= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV53294262; called by muse, mutect2, varscan2
- LYPD1 | c.321C>T p.N107= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs997017984, COSV61416771; called by muse, mutect2, varscan2
- MADCAM1 | c.810G>A p.P270= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs748389843, COSV99298740; called by muse, varscan2
- MAGEE1 | c.1803T>G p.A601= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100819523; called by muse, mutect2, varscan2
- MCM2 | c.1674G>A p.A558= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs376837416; called by muse, mutect2, varscan2
- MET | c.4056G>A p.V1352= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as COSV100577358; called by muse, mutect2, varscan2
- NHSL2 | c.1245G>T p.L415= (on ENST00000510661; = p.L781= on NM_001013627.2) | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV101030333; called by muse, mutect2, varscan2
- PHF24 | c.918C>A p.G306= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99646275; called by muse, mutect2, varscan2
- PKD1 | c.2664G>A p.E888= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1279359437, COSV99238999; called by muse, mutect2, varscan2
- PLXNA1 | c.585C>T p.S195= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs779765951, COSV99304036; called by muse, mutect2, varscan2
- QKI | c.315T>A p.P105= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV99276500; called by muse, mutect2, varscan2
- RASGRP1 | c.1902T>A p.P634= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100172289, COSV60365874; called by muse, mutect2, varscan2
- RGS3 | c.3351G>A p.K1117= (on ENST00000350696 / NM_001282923.2; = p.K836= on NM_130795.4) | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs1226619607, COSV100636985; called by muse, mutect2, varscan2
- RIN1 | c.1926G>A p.K642= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100254977; called by muse, mutect2, varscan2
- S1PR3 | c.396C>T p.I132= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV63980369; called by muse, mutect2, varscan2
- SLC8A1 | c.2883C>T p.F961= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100247368; called by muse, mutect2, varscan2
- UCK1 | c.471C>T p.F157= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs746443101, COSV100944134; called by muse, mutect2, varscan2
- XIRP2 | c.3678A>G p.E1226= (on ENST00000628543; = p.E1401= on NM_152381.6) | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as rs1268319895, COSV54696788, COSV54722905, COSV99739657; called by muse, mutect2, varscan2
- ZC3H12B | c.2202C>G p.P734= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV100162020; called by muse, mutect2, varscan2
- ZNF285 | c.201G>A p.S67= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs73557001; called by muse, mutect2, varscan2
- BABAM2 | c.1089-11034G>A | Intron (SNP) | VAF 19/84 reads (23%) | catalogued as COSV100568767; called by muse, mutect2, varscan2
- CCDC140 | n.701G>A | RNA (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99735372; called by muse, mutect2, varscan2
- DNAH8 | chr6:38722913 G>A | 5'Flank (SNP) | VAF 14/23 reads (61%) | catalogued as COSV59481432; called by muse, mutect2, varscan2
- OR52A4P | n.1014C>T | RNA (SNP) | VAF 14/51 reads (27%) | catalogued as rs148621452; called by muse, mutect2, varscan2
- PARGP1 | n.507C>T | RNA (SNP) | VAF 44/107 reads (41%) | called by muse, mutect2, varscan2
- TBC1D32 | c.2571-9433T>C | Intron (SNP) | VAF 22/47 reads (47%) | catalogued as COSV99251217; called by muse, mutect2, varscan2
